Somatic mutation profile of tumor specimen 0DN83S from CCDI case PBCBLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.9 years (2,161 days).
Specimen 0DN83S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f160c5c5-28ce-4887-89f8-fcafc4f2ec84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN83N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b3ad93a-a06f-44cb-98d5-5890e7281b60

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 5, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 287/337 reads (85%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 59/2374 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- HARS2 | c.821G>C p.C274S | Missense Mutation (SNP) | VAF 208/553 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV51226960; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 78/1736 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FKBP15 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 341/807 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- PKHD1 | c.8173+2T>C p.X2725_splice | Splice Site (SNP) | VAF 34/952 reads (4%) | called by muse, mutect2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 48/854 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- SLC6A16 | c.1835G>A p.W612* | Nonsense Mutation (SNP) | VAF 215/535 reads (40%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 5/92 reads (5%) | catalogued as rs1262556378; called by muse, mutect2
- FCHO2 | c.1173+13A>G | Intron (SNP) | VAF 28/640 reads (4%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- SPG7 | c.1642+11C>T | Intron (SNP) | VAF 207/441 reads (47%) | catalogued as rs778284438, COSV51951171; called by muse, mutect2, varscan2
- TNIP2 | c.657+88G>A | Intron (SNP) | VAF 52/95 reads (55%) | catalogued as rs972472019; called by mutect2, varscan2
